MMRF case MMRF_2324 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/9860a185-10db-48cc-94aa-320a8eafa930

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.5 years (24,277 days); ISS stage: II; Days to last known disease status: 756 days (2.1 years); Days to last follow up: 756 days (2.1 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 98 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 126 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 155 days; Days to treatment end: 155 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 275 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -21 (ECOG 1): M Protein 4.85 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 103 mg/dL; Immunoglobulin G 70.2 g/L; Immunoglobulin A 1.19 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 0.36 µg/mL; Hemoglobin 6.45 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.19 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 26 g/L; Total Protein 12.4 g/dL; Glucose 4.57 mmol/L.
- Day 56 (ECOG 1): M Protein 0.24 g/dL; Beta 2 Microglobulin 0.24 µg/mL; Hemoglobin 7.32 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 6.6 g/dL; Glucose 5.39 mmol/L.
- Day 147 (ECOG 1): M Protein 0.07 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.34 mg/dL; Immunoglobulin G 6.27 g/L; Immunoglobulin A 1.15 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 0.23 µg/mL; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 95 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 3.47 mmol/L.
- Day 237 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.985 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.783 mg/dL; Immunoglobulin G 4.98 g/L; Immunoglobulin A 0.63 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 0.28 µg/mL; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 5.45 mmol/L.
- Day 364 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.84 mg/dL; Immunoglobulin G 7.73 g/L; Immunoglobulin A 2.03 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 0.25 µg/mL; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 4.95 mmol/L.
- Day 455 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.04 mg/dL; Immunoglobulin G 7.93 g/L; Immunoglobulin A 2.18 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 2 µg/mL; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 118 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.2 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 5.01 mmol/L.
- Day 575 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.28 mg/dL; Immunoglobulin G 8.5 g/L; Immunoglobulin A 2.85 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 0.33 µg/mL; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 4.46 mmol/L.
- Day 665 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.1 mg/dL; Immunoglobulin G 7.69 g/L; Immunoglobulin A 2.44 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 0.31 µg/mL; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 5.56 mmol/L.
- Day 756 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 5.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.79 mg/dL; Immunoglobulin G 7.3 g/L; Immunoglobulin A 3.21 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 1.78 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 7.2 g/dL; Glucose 4.62 mmol/L.

Other clinical attributes
- Day -21: Weight: 97 kg; Height: 180 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lung Cancer.

Biospecimens (2 samples)
- Sample MMRF_2324_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -21 days.
- Sample MMRF_2324_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -21 days.
